Somatic mutation profile of tumor specimen TCGA-EJ-5512-01A (aliquot TCGA-EJ-5512-01A-01D-1576-08) from TCGA case TCGA-EJ-5512, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 46.9 years (17,127 days).
Specimen TCGA-EJ-5512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68272d3b-758d-4637-9c17-3c13a115af27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5512-10A (Blood Derived Normal), aliquot TCGA-EJ-5512-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c19afb7-568c-4163-a36f-7ee335658ffc

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52822112, COSV52825476; called by muse, mutect2, varscan2
- AGK | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 63/409 reads (15%) | catalogued as COSV62595957; called by muse, mutect2, varscan2
- AGK | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV62595959; called by muse, mutect2, varscan2
- ATF7IP | c.2863-1G>T p.X955_splice | Splice Site (SNP) | VAF 19/128 reads (15%) | catalogued as COSV53766228, COSV53774156; called by muse, varscan2
- ATG5 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 47/305 reads (15%) | catalogued as rs1562272472, COSV58347418; called by muse, mutect2, varscan2
- CFAP206 | c.992C>G p.T331S | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV51537098; called by muse, mutect2
- MTSS1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs759492868, COSV100275828, COSV61500070; called by muse, mutect2, varscan2
- NSMAF | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as COSV50700783; called by muse, mutect2, varscan2
- PARVB | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369299575, COSV58691398; called by muse, mutect2
- PCDHB14 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as COSV53386565; called by muse, mutect2
- PLA2G4A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs772018373, COSV66556935; called by muse, mutect2, varscan2
- ZNF438 | c.2452G>C p.G818R | Missense Mutation (SNP) | VAF 84/462 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV59200868; called by muse, mutect2, varscan2
- CD79B | c.213C>T p.S71= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs756340178, COSV50076332; called by muse, mutect2, varscan2
- OR6K2 | c.606C>A p.V202= | Silent (SNP) | VAF 36/258 reads (14%) | catalogued as COSV100656681, COSV62744216; called by muse, mutect2, varscan2
- SQOR | c.504G>T p.S168= | Silent (SNP) | VAF 67/369 reads (18%) | catalogued as COSV52941628, COSV52941884; called by muse, mutect2, varscan2
- MIR509-3 | n.54G>A | RNA (SNP) | VAF 86/220 reads (39%) | catalogued as rs782709356; called by muse, mutect2, varscan2
